Somatic mutation profile of tumor specimen TCGA-KQ-A41Q-01A (aliquot TCGA-KQ-A41Q-01A-11D-A339-08) from TCGA case TCGA-KQ-A41Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-KQ-A41Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d317e22-ea11-4ad7-aa16-81fa3eb68329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41Q-10D (Blood Derived Normal), aliquot TCGA-KQ-A41Q-10D-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da266614-4389-4e97-a573-ac1339567675

The open-access MAF lists 178 somatic variants for this specimen: 122 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 50, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 3, RNA 3, Frame Shift Ins 3, Intron 2, Splice Region 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RMND1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs886037772, COSV100323631, COSV60551269; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV62789572, COSV62791267; called by muse, mutect2, varscan2
- AATF | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as rs759338868; called by muse, mutect2, varscan2
- ACOT12 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs576654714, COSV56892736; called by muse, mutect2
- ADAM23 | c.2111A>T p.D704V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52225760; called by muse, mutect2, varscan2
- ADCY6 | c.2854C>G p.L952V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57166532; called by muse, mutect2, varscan2
- AKAP9 | c.641T>C p.L214S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62354819; called by muse, mutect2, varscan2
- ALDH16A1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as rs781770831, COSV53192575; called by muse, mutect2, varscan2
- ALG14 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs201781289; called by muse, mutect2, varscan2
- AMZ2 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63083610; called by muse, mutect2, varscan2
- ANKLE2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs745348245, COSV61711053; called by muse, mutect2, varscan2
- ANKRD55 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61949555; called by muse, mutect2, varscan2
- ARID1A | c.2038C>A p.P680T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61385392; called by muse, mutect2, varscan2
- ARNT | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV62231850; called by muse, mutect2, varscan2
- ATP8B1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.309); catalogued as COSV52178956; called by muse, mutect2, varscan2
- ATR | c.5830C>T p.L1944F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63386947, COSV63387161, COSV63391824; called by muse, mutect2, varscan2
- BAG5 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs756961001, COSV54572313; called by muse, mutect2, varscan2
- BPTF | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1223881213, COSV58838203; called by muse, mutect2, varscan2
- CA1 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56279715; called by muse, mutect2, varscan2
- CANX | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV56006157; called by muse, mutect2, varscan2
- CAP2 | c.636A>C p.T212= | Splice Region (SNP) | VAF 9/123 reads (7%) | catalogued as COSV57735576; called by muse, mutect2
- CDC42BPB | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs764023925, COSV63476380; called by muse, mutect2, varscan2
- CDH8 | c.1846C>G p.P616A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs761638294, COSV54889885; called by muse, mutect2, varscan2
- CHEK1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54025141; called by muse, mutect2, varscan2
- CIT | c.5108G>C p.C1703S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55878992; called by muse, mutect2, varscan2
- CLTA | c.486-2A>G p.X162_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV54255478; called by muse, mutect2, varscan2
- CLTC | c.3877C>G p.R1293G | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs141313166, COSV52251676; called by muse, mutect2, varscan2
- CNTNAP5 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV70479048, COSV70493114; called by muse, mutect2, varscan2
- COL14A1 | c.4255G>C p.D1419H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52864517; called by muse, mutect2, varscan2
- COQ8B | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs539108283, COSV54688498; called by muse, mutect2, varscan2
- CPT1B | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs748307991, COSV56417701; called by muse, mutect2, varscan2
- CTNND1 | c.2009C>T p.S670L (on ENST00000399050 / NM_001085458.2; = p.S664L on NM_001331.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV62384976, COSV62385365; called by muse, mutect2, varscan2
- CTSB | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs371200657, COSV61541130; called by muse, mutect2, varscan2
- DGKG | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.109); catalogued as COSV53967735; called by muse, mutect2, varscan2
- DISP3 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV53834900; called by muse, mutect2, varscan2
- DLGAP1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265206208, COSV59800524; called by muse, mutect2, varscan2
- DMBX1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs780635244, COSV63601891; called by muse, mutect2, varscan2
- DNAH7 | c.8272G>A p.D2758N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1281592868, COSV56770442; called by muse, mutect2, varscan2
- DUSP28 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1297178674, COSV56039260; called by muse, mutect2, varscan2
- ELMO3 | c.1594C>G p.L532V (on ENST00000652269; = p.L479V on NM_024712.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV58528066; called by muse, mutect2, varscan2
- ENPP6 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV57071089; called by muse, mutect2, varscan2
- EPHA5 | c.2236+1G>A p.X746_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV56631720, COSV56665397, COSV99895646; called by muse, mutect2, varscan2
- FADS2 | c.318C>T p.N106= | Splice Region (SNP) | VAF 22/31 reads (71%) | catalogued as rs144799113, COSV99608632; called by muse, varscan2
- FAM120B | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as rs568281525, COSV53007131; called by muse, mutect2, varscan2
- FNBP4 | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55451273; called by muse, mutect2, varscan2
- FSD2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58012105; called by muse, mutect2, varscan2
- FSIP1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV63226402; called by muse, varscan2
- FTH1 | c.388-2A>G p.X130_splice | Splice Site (SNP) | VAF 50/93 reads (54%) | catalogued as COSV56446281; called by muse, mutect2, varscan2
- FTSJ3 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.805); catalogued as COSV59563709; called by muse, mutect2, varscan2
- FTSJ3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1567753791, COSV59563711; called by muse, mutect2, varscan2
- FUS | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs374434160, COSV99568551; called by muse, mutect2
- GABARAP | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV56642713; called by muse, mutect2, varscan2
- GBF1 | c.1103C>T p.S368F (on ENST00000369983 / NM_001377137.1; = p.S367F on NM_004193.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV64148023; called by muse, mutect2, varscan2
- HLA-B | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV69522654; called by muse, varscan2
- IL1RAP | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV50767699; called by muse, mutect2, varscan2
- JAKMIP1 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs767418893, COSV51528850; called by muse, mutect2, varscan2
- LCA5L | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV55746796; called by muse, mutect2, varscan2
- LMAN2 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57425500; called by muse, mutect2, varscan2
- LMTK3 | c.4273C>A p.P1425T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV99540402; called by muse, mutect2, varscan2
- LPAR3 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65454623; called by muse, mutect2, varscan2
- LRCH4 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59644190; called by muse, mutect2, varscan2
- MIXL1 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64729349; called by muse, mutect2, varscan2
- MROH9 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768549118, COSV63012788; called by muse, mutect2, varscan2
- MS4A13 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65446085; called by muse, mutect2, varscan2
- MUC5B | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs1390952963, COSV101500273; called by muse, mutect2, varscan2
- MUC5B | c.14353G>C p.E4785Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV71591812, COSV71594558; called by muse, mutect2, varscan2
- NAPSA | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53798595; called by muse, mutect2, varscan2
- NCOA3 | c.1931C>G p.S644* | Nonsense Mutation (SNP) | VAF 18/156 reads (12%) | catalogued as COSV100507182, COSV100507475; called by muse, mutect2, varscan2
- NCOA5 | c.687G>C p.L229F | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51646718; called by muse, mutect2, varscan2
- NOTCH1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); catalogued as rs1182867386, COSV53079912; called by muse, mutect2, varscan2
- NUP98 | c.3034C>G p.R1012G (on ENST00000359171 / NM_001365126.1; = p.R995G on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV61436913; called by muse, mutect2, varscan2
- OR4M1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 88/602 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60062990; called by muse, mutect2, varscan2
- OR9G1 | c.785G>T p.R262I | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV56453298; called by muse, mutect2
- PCDH12 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs781085245, COSV51523621; called by muse, mutect2, varscan2
- PCLO | c.1441C>G p.P481A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV61657411, COSV61657490; called by muse, mutect2, varscan2
- PHF3 | c.3223G>C p.E1075Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV50333032; called by muse, mutect2, varscan2
- PLEKHG6 | c.2197A>G p.M733V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs758035047, COSV50608410; called by muse, mutect2, varscan2
- PLXND1 | c.4141C>T p.Q1381* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100139582; called by muse, varscan2
- PPARG | c.490C>T p.R164W (on ENST00000287820 / NM_015869.5; = p.R134W on NM_005037.7) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170672782, CM148624, COSV55144655; called by muse, mutect2, varscan2
- PPCS | c.595_605del p.S199Tfs*17 | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | catalogued as COSV65333834; called by mutect2, pindel, varscan2
- PPP1R15B | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65816361; called by muse, mutect2, varscan2
- PTPRC | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV61418789; called by muse, mutect2, varscan2
- PTPRS | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53632323; called by muse, mutect2, varscan2
- RAB40AL | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV54435472; called by muse, mutect2, varscan2
- RB1 | c.1182_1183insA p.Q395Tfs*11 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | catalogued as COSV57320731; called by mutect2, pindel, varscan2
- RGS18 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV66509555; called by muse, mutect2, varscan2
- RP1 | c.4016G>T p.C1339F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55123834; called by muse, mutect2, varscan2
- SCN3B | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV54798318; called by muse, varscan2
- SCYL2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV62570265; called by muse, mutect2, varscan2
- SERPINA12 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV57945680; called by muse, mutect2, varscan2
- SFTPA2 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as COSV100958763; called by muse, mutect2, varscan2
- SLC6A15 | c.2110C>G p.L704V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV57027642; called by muse, mutect2, varscan2
- SNRPA | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV54682294; called by muse, mutect2, varscan2
- SRBD1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99764963; called by muse, mutect2, varscan2
- STC2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs775172802, COSV54178219; called by muse, mutect2, varscan2
- STON2 | c.1307C>G p.S436C (on ENST00000649389 / NM_001366849.2; = p.S379C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV50851158; called by muse, mutect2, varscan2
- SUPT6H | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV100112338; called by muse, mutect2, varscan2
- SV2C | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59218954, COSV59226666; called by muse, mutect2, varscan2
- SYMPK | c.2877G>C p.M959I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99841646, COSV99841749; called by muse, mutect2
- TAS2R16 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.524); catalogued as COSV50798315; called by muse, mutect2, varscan2
- TBCCD1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV58663094; called by muse, mutect2, varscan2
- TMEM26 | c.852G>C p.Q284H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs1247191587, COSV99515569; called by muse, mutect2
- UAP1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54852884; called by muse, mutect2, varscan2
- USP54 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766032494, COSV60446113; called by muse, mutect2, varscan2
- VAV2 | c.2489G>A p.R830Q (on ENST00000371850 / NM_001134398.2; = p.R791Q on NM_003371.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374240487; called by muse, mutect2, varscan2
- VPS8 | c.1130T>C p.V377A (on ENST00000625842 / NM_001349294.1; = p.V375A on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54993676; called by muse, mutect2, varscan2
- WSB2 | c.1108A>T p.K370* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99969831; called by muse, mutect2, varscan2
- ZC3H10 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99230489; called by muse, mutect2, varscan2
- ZCWPW1 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV52202069; called by muse, mutect2, varscan2
- ZFYVE28 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747613925, COSV52115703; called by muse, mutect2, varscan2
- ZNF135 | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57884846; called by muse, mutect2, varscan2
- ZNF432 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV55417984; called by muse, mutect2, varscan2
- ZNF432 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as rs770370219, COSV99659208; called by muse, mutect2, varscan2
- ZNF678 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as COSV59382816, COSV59385009, COSV59386584; called by muse, mutect2, varscan2
- ZNF827 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs771099583, COSV65224432, COSV65230616; called by muse, mutect2, varscan2
- ANKS1A | c.1438_1446del p.S480_S482del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ARID1A | c.2272del p.Q758Rfs*75 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- CDKN1A | c.110dup p.M38Nfs*10 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- CNOT10 | c.1881_1888del p.K628Pfs*30 | Frame Shift Del (DEL) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- NAP1L2 | c.92dup p.E32Gfs*4 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- POLR2A | c.5883C>G p.I1961M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STRN4 | c.403_407del p.L135Vfs*81 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ACOT7 | c.501G>A p.L167= (on ENST00000377855 / NM_181864.3; = p.L157= on NM_007274.4) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1468786046, COSV64114979; called by muse, mutect2, varscan2
- ACTL8 | c.165C>T p.I55= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs752312335, COSV64862384; called by muse, mutect2, varscan2
- AHNAK2 | c.16980G>A p.E5660= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV60925551; called by muse, mutect2, varscan2
- ARHGAP28 | c.675C>T p.D225= (on ENST00000383472 / NM_001366230.1; = p.D66= on NM_001010000.3) | Silent (SNP) | VAF 54/174 reads (31%) | catalogued as rs749881865, COSV51643403; called by muse, mutect2, varscan2
- ARID1A | c.3558G>A p.G1186= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV61385409; called by muse, mutect2, varscan2
- BRWD1 | c.798C>G p.L266= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV58123493; called by muse, mutect2, varscan2
- BTN3A1 | c.738G>A p.Q246= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV50025257; called by muse, mutect2, varscan2
- C7orf31 | c.834C>T p.L278= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52219478; called by muse, mutect2, varscan2
- CACNA1G | c.5637C>T p.S1879= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs774882008, COSV61735234; called by muse, mutect2
- CCDC40 | c.2337C>T p.R779= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs764258494, COSV66477828; called by muse, mutect2, varscan2
- CDC42BPB | c.1839C>T p.D613= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs750097209, COSV63476382; called by muse, mutect2, varscan2
- CEP192 | c.7221C>T p.L2407= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as rs749938317, COSV58068981, COSV58071896; called by muse, mutect2, varscan2
- CLEC5A | c.189C>T p.T63= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV69397355; called by muse, mutect2, varscan2
- DYNC1H1 | c.13089G>A p.K4363= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV64140710; called by muse, mutect2, varscan2
- EGR2 | c.810C>T p.N270= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54348431; called by muse, mutect2, varscan2
- EIF3L | c.492C>T p.F164= | Silent (SNP) | VAF 123/170 reads (72%) | catalogued as COSV67739290; called by muse, varscan2
- FBXO2 | c.801C>T p.V267= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as COSV62813918; called by muse, mutect2, varscan2
- FTSJ3 | c.2247G>A p.K749= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV63790977; called by muse, varscan2
- FTSJ3 | c.1209G>A p.L403= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs141059832, COSV59563702; called by muse, varscan2
- GABRG2 | c.1416G>C p.G472= (on ENST00000361925 / NM_001375343.1; = p.G432= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV62721309; called by muse, mutect2, varscan2
- GPR26 | c.813C>T p.I271= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs767515588, COSV52935911; called by muse, mutect2, varscan2
- GPR4 | c.963C>T p.L321= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV59917900; called by muse, mutect2
- HSPA12B | c.708G>A p.Q236= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs376594636, COSV54768637; called by muse, mutect2, varscan2
- HTT | c.8583G>A p.V2861= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV61867238; called by mutect2, varscan2
- KALRN | c.3405C>T p.F1135= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs776467881, COSV53755718, COSV99562764; called by muse, mutect2, varscan2
- KCNN3 | c.564C>A p.L188= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV55224022, COSV99678075; called by muse, mutect2, varscan2
- KRT71 | c.1314C>T p.S438= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs771018687, COSV57292450; called by muse, mutect2
- MDN1 | c.14988G>A p.E4996= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV65528011; called by muse, mutect2, varscan2
- NOD2 | c.2739C>T p.D913= | Silent (SNP) | VAF 69/351 reads (20%) | catalogued as rs104895451, COSV56053857; ClinVar: not provided / likely benign; called by muse, mutect2, varscan2
- OR10H1 | c.144C>T p.T48= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs142314142; called by muse, mutect2, varscan2
- OR4M1 | c.600C>T p.I200= | Silent (SNP) | VAF 87/373 reads (23%) | catalogued as COSV60060078, COSV60062994; called by muse, mutect2, varscan2
- P2RY1 | c.357C>T p.F119= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1419231289, COSV59310187; called by muse, mutect2, varscan2
- PCNX3 | c.1230G>C p.R410= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58421237; called by muse, mutect2, varscan2
- PLEC | c.11556G>A p.L3852= (on ENST00000322810 / NM_201380.4; = p.L3742= on NM_000445.5) | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV59678181; called by muse, mutect2
- POLR2C | c.219C>T p.L73= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as COSV52646996; called by muse, varscan2
- PRDM1 | c.1374C>T p.H458= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs779643872, COSV64846391; called by muse, mutect2, varscan2
- RASGEF1C | c.475C>T p.L159= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV63183540; called by muse, mutect2, varscan2
- RB1CC1 | c.2685G>A p.L895= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV50266734; called by muse, mutect2, varscan2
- SETX | c.4027C>T p.L1343= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56378244, COSV56388814; called by muse, mutect2, varscan2
- SLC5A7 | c.1329C>A p.L443= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV50898782; called by muse, mutect2, varscan2
- SRBD1 | c.1542G>A p.E514= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TNFRSF10D | c.630T>C p.Y210= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1035208560, COSV57037245; called by muse, mutect2, varscan2
- TRMT9B | c.1263C>T p.C421= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs551128894, COSV71600581; called by muse, mutect2, varscan2
- TSGA10IP | c.54G>A p.P18= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs369328949; called by muse, mutect2, varscan2
- TTLL3 | c.618G>A p.A206= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs758692951, COSV59615357; called by muse, mutect2, varscan2
- TTN | c.8010T>C p.D2670= (on ENST00000591111; = p.D2624= on NM_003319.4) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1451256808, COSV60262142; called by muse, mutect2, varscan2
- TULP2 | c.732C>T p.G244= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs548667962, COSV55479568; called by muse, mutect2, varscan2
- UGT1A6 | c.1350G>A p.P450= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs368860136, COSV100530391; called by muse, mutect2, varscan2
- ZNF233 | c.585G>A p.Q195= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV61934378; called by muse, mutect2, varscan2
- ZNF454 | c.735A>G p.E245= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV60769761; called by muse, mutect2, varscan2
- AC073310.1 | n.740C>G | RNA (SNP) | VAF 25/91 reads (27%) | catalogued as rs1266997668; called by muse, mutect2, varscan2
- CCDC18 | c.-3+417G>A | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as COSV58146516; called by muse, mutect2, varscan2
- DCHS2 | n.90T>C | RNA (SNP) | VAF 5/22 reads (23%) | catalogued as COSV59736343; called by muse, mutect2, varscan2
- MITF | c.102-12817C>T | Intron (SNP) | VAF 23/88 reads (26%) | catalogued as COSV58888449; called by muse, mutect2, varscan2
- POM121 | chr7:72949331 G>C | 3'Flank (SNP) | VAF 9/38 reads (24%) | catalogued as rs558588169, COSV99988151; called by muse, mutect2, varscan2
- SSPOP | n.7637C>T | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as rs374281876; called by muse, mutect2, varscan2
